Gene-level copy-number profile of tumor specimen TCGA-J2-8194-01A from TCGA case TCGA-J2-8194, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,441 days).
Specimen TCGA-J2-8194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d0614ea5-41e1-43d8-9080-20e49c8c63f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J2-8194-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c9a9c54-69ca-4f09-8a5a-0ca53c6ec2f8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 908; copy number 2: 6,789; copy number 3: 1,152; copy number 4: 33,381; copy number 5: 10,218; copy number 6: 3,768; copy number 7: 3,138; copy number 8: 21; copy number 9: 105; copy number 11: 296; copy number 12: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J2-8194-01A-11D-2237-01): tumor purity 0.44, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 439 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:18,418,662–54,607,131, 401 genes, copy number 9–11 (broad region; genes not listed).
- chr4:69,721,167–71,572,087, 38 genes, copy number 12: SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP, PRR27, ODAM, FDCSP, CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN, AMBN, ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, U6, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP.

Autosomal genes at a single copy (total copy number 1): 908. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
